Somatic mutation profile of tumor specimen TCGA-60-2703-01A (aliquot TCGA-60-2703-01A-11D-2042-08) from TCGA case TCGA-60-2703, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.9 years (27,003 days).
Specimen TCGA-60-2703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70d28e73-fef1-400c-9ab0-e448859ec1de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2703-11A (Solid Tissue Normal), aliquot TCGA-60-2703-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed8bdd25-cd38-4b25-b9ce-bbd1e8f4d9ed

The open-access MAF lists 307 somatic variants for this specimen: 231 protein-altering or splice-affecting, 66 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 66, Nonsense Mutation 9, Frame Shift Del 9, RNA 5, Splice Site 4, Intron 3, Nonstop Mutation 1, In Frame Del 1, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1085G>T p.C362F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs1457529291, COSV99447218; called by muse, mutect2, varscan2
- AC097636.1 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101469684, COSV71309723; called by muse, mutect2, varscan2
- ACSM2A | c.1012G>T p.G338W (on ENST00000219054; = p.G259W on NM_001308169.2) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99525498; called by muse, mutect2, varscan2
- ACSM5 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs748617727, COSV100089269; called by muse, mutect2, varscan2
- ADAMTS18 | c.194C>A p.T65K | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as COSV51405850, COSV99273630; called by muse, mutect2, varscan2
- ADAMTS19 | c.727A>T p.S243C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99179676; called by muse, mutect2, varscan2
- ADGRB3 | c.3256G>C p.A1086P | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as COSV99486252; called by muse, mutect2, varscan2
- ADGRG4 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99796178; called by muse, mutect2, varscan2
- AGBL1 | c.3258G>C p.W1086C | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.187); catalogued as COSV101223900; called by muse, mutect2, varscan2
- ALPK1 | c.1681G>T p.D561Y | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV99454773; called by muse, mutect2, varscan2
- ALS2 | c.2065A>T p.M689L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV99969752; called by muse, mutect2
- AOC2 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs143262935; called by muse, mutect2, varscan2
- AOC3 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV100396127, COSV100396158; called by muse, mutect2, varscan2
- APC | c.1051G>T p.G351* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99969110; called by muse, mutect2, varscan2
- APC | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99969111; called by muse, mutect2, varscan2
- APCS | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99661417; called by muse, mutect2, varscan2
- ARL5A | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV54469871, COSV99706730; called by muse, mutect2, varscan2
- ASXL3 | c.5479C>T p.P1827S | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99325841; called by muse, mutect2
- ATIC | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99378026; called by muse, mutect2
- ATP2A1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs908803462, COSV63920560; called by muse, mutect2, varscan2
- B4GALT4 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100785834; called by muse, mutect2
- BMPR2 | c.2330A>G p.H777R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.574); catalogued as COSV101001595; called by muse, mutect2, varscan2
- BRD1 | c.2641G>T p.V881L (on ENST00000216267 / NM_001349940.1; = p.V1012L on NM_001304808.3) | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV99350037; called by muse, mutect2, varscan2
- C14orf28 | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.257); catalogued as COSV57334235; called by muse, mutect2, varscan2
- CCDC39 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV99870093; called by muse, mutect2, varscan2
- CCT8L2 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100742944; called by muse, mutect2, varscan2
- CD163 | c.1967A>T p.E656V | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776013; called by muse, mutect2, varscan2
- CD226 | c.474G>T p.W158C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as COSV99711354; called by muse, mutect2, varscan2
- CD5L | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV63823349; called by muse, mutect2
- CDCA7 | c.593A>G p.E198G (on ENST00000347703 / NM_145810.3; = p.E277G on NM_031942.5) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV100143674; called by muse, mutect2
- CDH12 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV66437673; called by muse, mutect2
- CDH18 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV56904415, COSV99937016, COSV99937597; called by muse, mutect2, varscan2
- CDK14 | c.1154+2T>A p.X385_splice (on ENST00000380050 / NM_001287135.2; = p.X367_splice on NM_012395.3) | Splice Site (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99726246; called by muse, mutect2, varscan2
- CDON | c.1743C>G p.I581M | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99701738; called by muse, mutect2
- CFAP47 | c.2668G>T p.V890L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV52892854, COSV99935568; called by muse, mutect2, varscan2
- CHD9 | c.1666A>G p.T556A | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1192490265, COSV101272161; called by muse, mutect2, varscan2
- CHIA | c.1350C>A p.C450* (on ENST00000343320; = p.C342* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as rs781067947, COSV100588763; called by muse, mutect2
- CHST3 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV100910428; called by muse, mutect2, varscan2
- CIP2A | c.1843T>A p.C615S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99843059; called by muse, mutect2
- CLMP | c.764T>A p.L255Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV101507427; called by muse, mutect2
- CNP | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57270528; called by muse, mutect2
- CNTN3 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV55180739; called by muse, mutect2, varscan2
- COL5A2 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV66409601; called by muse, mutect2
- CSH1 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.907); catalogued as COSV100298405, COSV60242550; called by muse, mutect2, varscan2
- DALRD3 | c.950T>C p.V317A (on ENST00000341949 / NM_001009996.3; = p.V150A on NM_018114.5) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100482874; called by muse, mutect2, varscan2
- DENND5B | c.2322G>C p.E774D | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100171880; called by muse, mutect2, varscan2
- DMKN | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV100303830; called by muse, mutect2
- DMKN | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100303832, COSV60088500; called by muse, mutect2, varscan2
- DNAJA2 | c.532A>T p.M178L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV100398911; called by muse, mutect2
- DOCK10 | c.5093T>A p.L1698Q | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99290765; called by muse, mutect2
- DPYD | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs927463053, COSV100929230; called by muse, mutect2
- DRD3 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV99879581; called by muse, mutect2, varscan2
- ELF1 | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99523239; called by muse, mutect2, varscan2
- EML2 | c.1598-1G>T p.X533_splice | Splice Site (SNP) | VAF 23/112 reads (21%) | catalogued as COSV99840265; called by muse, mutect2, varscan2
- ENPP3 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100717757; called by muse, mutect2
- FABP7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100737995; called by muse, mutect2, varscan2
- FAM135B | c.3971C>G p.A1324G | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52739973, COSV99425923; called by muse, mutect2, varscan2
- FAM135B | c.3266G>C p.S1089T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1328929080, COSV99424272, COSV99425927; called by muse, mutect2
- FAM135B | c.2927del p.P976Rfs*14 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as COSV52733506; called by mutect2, pindel*, varscan2
- FAM135B | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99425930; called by muse, mutect2, varscan2
- FBXO10 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs536164018, COSV52832293; called by muse, mutect2
- FBXO11 | c.2209A>T p.I737L (on ENST00000403359 / NM_001190274.2; = p.I653L on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99316521; called by muse, mutect2, varscan2
- FBXO7 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs752994693, COSV99832838; called by muse, mutect2
- FBXW7 | c.376del p.D126Ifs*43 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as COSV55896130; called by mutect2, pindel, varscan2
- FLG | c.6532G>A p.D2178N | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.313); catalogued as COSV64243174; called by muse, mutect2
- FLT3 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as COSV99609654; called by muse, mutect2
- FN1 | c.4427G>A p.R1476K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); catalogued as rs1559402454, COSV100117743; called by muse, varscan2
- FSD2 | c.788T>C p.L263S | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100575232; called by muse, mutect2, varscan2
- GABRG1 | c.79T>A p.L27I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV99778481; called by muse, mutect2, varscan2
- GJC1 | c.1144A>G p.T382A | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100395212; called by muse, mutect2
- GLRA3 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.395); catalogued as COSV99927872; called by mutect2, varscan2
- GPATCH2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100861802; called by muse, varscan2
- GPR156 | c.1792A>T p.M598L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100251600; called by muse, mutect2, varscan2
- GRM3 | c.1178T>A p.V393E | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100862722, COSV64473431; called by muse, mutect2, varscan2
- HCN1 | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100301439; called by muse, mutect2
- HDAC4 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV100613946; called by muse, varscan2
- HEPH | c.480C>A p.S160R (on ENST00000343002; = p.S214R on NM_138737.5) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.744); catalogued as COSV100295296; called by muse, mutect2, varscan2
- HIF3A | c.415G>A p.E139K (on ENST00000377670 / NM_152795.4; = p.E70K on NM_022462.4) | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355974; called by muse, mutect2, varscan2
- HNF4G | c.433C>T p.Q145* (on ENST00000354370 / NM_001330561.2; = p.Q192* on NM_004133.5) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100584817; called by muse, mutect2, varscan2
- HOXC13 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV99673548; called by muse, mutect2
- HSF2 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100869702; called by muse, mutect2, varscan2
- HUNK | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99528154, COSV99528758; called by muse, mutect2, varscan2
- INPP4A | c.1442A>C p.Y481S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.311); catalogued as COSV99304682; called by muse, mutect2
- INSRR | c.3511A>T p.T1171S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.526); catalogued as COSV100947858, COSV63876056; called by muse, mutect2, varscan2
- KALRN | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375108520; called by muse, mutect2, varscan2
- KIAA1549L | c.2282T>A p.L761Q (on ENST00000321505; = p.L1058Q on NM_012194.3) | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV99684007; called by muse, mutect2, varscan2
- KIFAP3 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.438); catalogued as rs1322722615, COSV100847052; called by mutect2, varscan2
- LACC1 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100354736; called by muse, mutect2, varscan2
- LAPTM4B | c.919G>T p.A307S (on ENST00000445593; = p.A216S on NM_018407.6) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as COSV101503498; called by muse, mutect2, varscan2
- LHX8 | c.373A>C p.K125Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99634097; called by muse, mutect2, varscan2
- LILRB3 | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1335341048; called by muse, mutect2
- LIPF | c.60G>T p.L20F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV99490479; called by muse, mutect2, varscan2
- LRFN5 | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99984817; called by muse, mutect2, varscan2
- MAP3K21 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV100786291; called by muse, mutect2
- MAPRE1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100980405; called by muse, mutect2, varscan2
- MARK1 | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100857419; called by muse, mutect2
- MDGA2 | c.998G>T p.C333F (on ENST00000399232 / NM_001113498.2; = p.C35F on NM_182830.4) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100637680; called by muse, mutect2
- MED12L | c.1046C>G p.S349* | Nonsense Mutation (SNP) | VAF 35/220 reads (16%) | catalogued as COSV99854056; called by muse, mutect2, varscan2
- MERTK | c.2344G>T p.D782Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99775004; called by muse, mutect2, varscan2
- MME | c.2076G>T p.Q692H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100852476; called by muse, mutect2
- MS4A12 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751500031, COSV99189364; called by muse, mutect2, varscan2
- MTTP | c.1834G>A p.G612R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99645427; called by muse, mutect2, varscan2
- MUSK | c.2225C>A p.A742D | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504722; called by muse, mutect2, varscan2
- MYH7 | c.2149G>C p.D717H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100806225, COSV100806384; called by muse, mutect2, varscan2
- MYH8 | c.2622G>T p.K874N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV101238551; called by muse, mutect2, varscan2
- NCOA2 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV101476032; called by muse, mutect2, varscan2
- NCOA7 | c.1826C>G p.S609C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99997412, COSV99997506; called by muse, mutect2, varscan2
- NEDD1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99901198; called by muse, mutect2, varscan2
- NETO1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100199271; called by muse, mutect2
- NFYC | c.1339C>T p.P447S (on ENST00000308733 / NM_001308114.1; = p.P324S on NM_014223.5) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs770195566, COSV100438629; called by muse, mutect2, varscan2
- NKAIN3 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV100133423, COSV100135416; called by muse, mutect2
- NKAPL | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100642558, COSV59197704; called by muse, mutect2
- NPY5R | c.862_864del p.R288del | In Frame Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs750456846; called by pindel, varscan2
- NRCAM | c.1043C>A p.A348D (on ENST00000379028 / NM_001371124.1; = p.A342D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61053678; called by muse, mutect2, varscan2
- NRG4 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100555498; called by muse, mutect2, varscan2
- OCRL | c.2692A>G p.S898G | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100843512; called by muse, mutect2, varscan2
- OPRL1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100402197; called by muse, mutect2, varscan2
- OR10Z1 | c.533T>C p.F178S | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100779055, COSV63524184; called by muse, mutect2, varscan2
- OR2A4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1248407547, COSV59576207; called by mutect2, varscan2
- OR2L2 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100824188, COSV63562326; called by muse, mutect2
- OR5AN1 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100004412; called by muse, mutect2
- OR5AU1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436177; called by muse, varscan2
- OR5B12 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100222487; called by muse, mutect2, varscan2
- OR5B3 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100512040, COSV58679008; called by muse, mutect2, varscan2
- OR5L1 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV100450153, COSV100450238; called by muse, mutect2, varscan2
- OXR1 | c.1744T>A p.Y582N (on ENST00000442977 / NM_001198532.1; = p.Y581N on NM_018002.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100367555; called by muse, mutect2, varscan2
- PANX1 | c.1060A>T p.I354F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV99921927, COSV99921975; called by muse, mutect2
- PARP8 | c.1238G>T p.S413I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.462); catalogued as COSV99892219; called by muse, mutect2, varscan2
- PBRM1 | c.3685A>G p.I1229V (on ENST00000296302 / NM_001366071.2; = p.I1204V on NM_018313.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.217); catalogued as COSV99970062; called by muse, mutect2, varscan2
- PCDH7 | c.2993C>T p.S998F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688533; called by muse, mutect2, varscan2
- PCDHGA1 | c.2364G>C p.K788N | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); catalogued as COSV100966031, COSV65298898; called by muse, mutect2, varscan2
- PCDHGB5 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1355149152; called by mutect2, varscan2
- PCLO | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100435157, COSV104415120; called by muse, mutect2
- PDP1 | c.188G>C p.W63S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99892686; called by muse, mutect2, varscan2
- PGM2L1 | c.1612A>T p.S538C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53348442; called by muse, mutect2, varscan2
- PIGG | c.1871A>G p.D624G (on ENST00000453061 / NM_001127178.3; = p.D616G on NM_017733.4) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99574156; called by muse, mutect2, varscan2
- PKD1 | c.10181G>T p.G3394V (on ENST00000262304 / NM_001009944.3; = p.G3393V on NM_000296.4) | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV99238652; called by muse, mutect2, varscan2
- PLCL1 | c.2184C>G p.I728M | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1163258037, COSV101407219; called by muse, mutect2, varscan2
- PLSCR4 | c.749G>C p.C250S | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV100724292; called by muse, mutect2, varscan2
- POTEE | c.1656C>A p.F552L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100388527; called by muse, mutect2, varscan2
- POTEH | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV58879567; called by muse, varscan2
- PRKCD | c.81C>G p.F27L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV100387995; called by muse, mutect2, varscan2
- PRPF31 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100320078; called by muse, mutect2, varscan2
- PRPF31 | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320080; called by muse, mutect2, varscan2
- PRRG3 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.921); catalogued as COSV100948670; called by muse, mutect2, varscan2
- PTPN14 | c.2410C>G p.L804V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100872827, COSV65282068; called by muse, mutect2, varscan2
- PXDN | c.3733G>C p.D1245H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99414338; called by muse, mutect2, varscan2
- RAG2 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100271420; called by muse, mutect2
- RASSF2 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101040862; called by muse, varscan2
- RIF1 | c.2450T>C p.L817P | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99690932; called by muse, mutect2, varscan2
- RYR2 | c.5227A>T p.N1743Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100772042; called by muse, mutect2, varscan2
- SAMD4B | c.1029A>T p.K343N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100080526; called by muse, mutect2, varscan2
- SARS1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV99321407; called by muse, mutect2, varscan2
- SCEL | c.1628G>T p.R543L (on ENST00000349847 / NM_144777.3; = p.R523L on NM_003843.4) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100583092; called by muse, mutect2, varscan2
- SCN10A | c.4727G>A p.R1576H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs777606824, COSV71860179; called by muse, mutect2, varscan2
- SEMA3E | c.2302C>A p.L768M | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.372); catalogued as COSV100319175; called by muse, varscan2
- SIGLEC1 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV52463198, COSV99169820; called by muse, mutect2
- SLC12A5 | c.2774C>A p.T925N (on ENST00000454036 / NM_001134771.2; = p.T902N on NM_020708.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99716497; called by muse, mutect2, varscan2
- SLC15A1 | c.1672G>T p.V558F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100919517; called by muse, mutect2
- SLC18A1 | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99368809; called by muse, mutect2, varscan2
- SLC2A9 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305181; called by muse, mutect2, varscan2
- SLC9A4 | c.2083G>T p.A695S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs769508547, COSV99763353; called by muse, mutect2, varscan2
- SLCO1B1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV99917904; called by muse, mutect2
- SLCO6A1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101134720; called by muse, mutect2, varscan2
- SLCO6A1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs760662671, COSV101134721; called by muse, mutect2, varscan2
- SLITRK3 | c.2114G>C p.C705S | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV99579449, COSV99579715; called by muse, mutect2, varscan2
- SMAD9 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV100614895; called by muse, mutect2, varscan2
- SPATA17 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs368705475, COSV65120698; called by muse, mutect2, varscan2
- SPATA31D1 | c.3343C>G p.L1115V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.093); catalogued as COSV100782931; called by muse, mutect2, varscan2
- SPATA31E1 | c.1004C>A p.T335N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100350779; called by muse, mutect2, varscan2
- SPTB | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101072325, COSV67630315; called by muse, mutect2, varscan2
- ST14 | c.1320C>A p.F440L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99598981; called by muse, mutect2, varscan2
- ST18 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99390507; called by muse, mutect2
- ST6GAL2 | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | PolyPhen possibly damaging (0.764); catalogued as COSV100868172; called by muse, mutect2
- STK17B | c.1119G>T p.*373Yext*5 | Nonstop Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99826240; called by muse, mutect2
- STRN4 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV99623453, COSV99623878; called by muse, mutect2, varscan2
- SYNE1 | c.9404T>A p.L3135Q (on ENST00000367255 / NM_182961.4; = p.L3142Q on NM_033071.3) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV99573110; called by muse, mutect2, varscan2
- TAAR2 | c.926C>T p.T309I (on ENST00000367931 / NM_001033080.1; = p.T264I on NM_014626.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV99255735; called by muse, mutect2
- TACR3 | c.475C>G p.R159G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs574875874, COSV100510729, COSV59208503; called by mutect2, varscan2
- TAF1C | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100499729; called by muse, mutect2, varscan2
- TAF5L | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV99273480; called by muse, mutect2, varscan2
- TAS2R1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as COSV101225824; called by muse, mutect2, varscan2
- TASP1 | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100534650, COSV100534734; called by muse, mutect2, varscan2
- TBXT | c.1227C>A p.D409E | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99752749; called by muse, mutect2, varscan2
- THSD1 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99319000; called by muse, mutect2, varscan2
- TIMMDC1 | c.708-2A>T p.X236_splice | Splice Site (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99956241; called by muse, mutect2, varscan2
- TMEM102 | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99548442; called by muse, mutect2, varscan2
- TMPRSS11A | c.420A>C p.Q140H | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV100602766; called by muse, mutect2, varscan2
- TMTC1 | c.2050G>A p.E684K (on ENST00000539277 / NM_001193451.2; = p.E576K on NM_175861.3) | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.634); catalogued as rs1050659135, COSV99760416; called by muse, mutect2, varscan2
- TNXB | c.6647C>T p.P2216L (on ENST00000647633; = p.P1969L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs773297077, COSV100926208; called by muse, mutect2, varscan2
- TRPM7 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV100540120; called by muse, mutect2, varscan2
- TSHR | c.1654C>A p.L552I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV53330700; called by muse, mutect2, varscan2
- TSPYL1 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100889611; called by muse, mutect2
- TTC38 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV101123919; called by muse, mutect2, varscan2
- TTN | c.83077G>C p.D27693H (on ENST00000591111; = p.D20269H on NM_003319.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV100622542; called by mutect2, varscan2
- TTN | c.51603C>G p.C17201W (on ENST00000591111; = p.C9777W on NM_003319.4) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | PolyPhen probably damaging (0.998); catalogued as COSV100622544; called by muse, mutect2
- UBE2J1 | c.429-1G>C p.X143_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV70561024, COSV70561783; called by mutect2, varscan2
- UBQLNL | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100975149; called by muse, mutect2, varscan2
- UGGT1 | c.2943G>T p.K981N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99390968; called by muse, mutect2, varscan2
- USPL1 | c.2556A>T p.E852D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.074); catalogued as COSV99687486; called by muse, mutect2, varscan2
- VIL1 | c.1670G>A p.W557* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as rs1170342891, COSV99945739; called by muse, mutect2, varscan2
- WNT2 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs180913783, COSV99626273; called by muse, mutect2, varscan2
- XIRP2 | c.5822C>A p.S1941Y (on ENST00000628543; = p.S2116Y on NM_152381.6) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99745553; called by muse, mutect2, varscan2
- YES1 | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as rs1354676545, COSV58848775; called by muse, mutect2, varscan2
- ZBTB45 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV100657761; called by muse, mutect2
- ZC3H3 | c.2029A>T p.N677Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99368286; called by muse, mutect2
- ZEB1 | c.1669C>A p.Q557K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100314747; called by muse, mutect2, varscan2
- ZFHX4 | c.1090T>A p.W364R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51460569, COSV99265625; called by muse, mutect2, varscan2
- ZFHX4 | c.6833G>C p.R2278P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51499657, COSV99265627; called by muse, mutect2, varscan2
- ZIC4 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV101268008, COSV101268081; called by muse, mutect2, varscan2
- ZIM3 | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 15/116 reads (13%) | catalogued as COSV99517999, COSV99518403; called by muse, mutect2, varscan2
- ZNF18 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100503152; called by muse, mutect2
- ZNF182 | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100527139; called by muse, mutect2, varscan2
- ZNF263 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.977); catalogued as COSV54595520; called by muse, mutect2, varscan2
- ZNF639 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs761271239, COSV100418463; called by muse, mutect2, varscan2
- ZNF655 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs754701419, COSV99402259; called by muse, mutect2, varscan2
- ZNF780B | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.067); catalogued as COSV99665956; called by muse, mutect2, varscan2
- ZNF804B | c.3978T>G p.H1326Q | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV100305012; called by muse, mutect2, varscan2
- ACACA | c.3442T>C p.Y1148H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ADGRG1 | c.674del p.M225Rfs*98 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | called by mutect2, pindel, varscan2
- CNGA3 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- GAS2L2 | c.1449C>A p.F483L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- HIRA | c.707del p.Y236Sfs*8 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- KLF11 | c.908del p.L303* | Frame Shift Del (DEL) | VAF 19/116 reads (16%) | called by mutect2, pindel, varscan2
- KMT2D | c.14786del p.P4929Lfs*66 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by pindel, varscan2
- LHX9 | c.263A>G p.D88G | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- LHX9 | c.445_446del p.A149Pfs*98 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by pindel, varscan2
- RIMKLB | c.1007dup p.A337Sfs*6 | Frame Shift Ins (INS) | VAF 53/185 reads (29%) | called by mutect2, pindel, varscan2
- SYTL5 | c.850_854del p.S284Gfs*6 | Frame Shift Del (DEL) | VAF 7/12 reads (58%) | called by mutect2, varscan2
- USP19 | c.1653del p.V552Cfs*19 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.1167G>T p.L389= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99896384; called by muse, mutect2, varscan2
- ASMTL | c.984G>T p.V328= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101187852; called by muse, mutect2, varscan2
- C19orf12 | c.430C>T p.L144= (on ENST00000392278 / NM_001031726.3; = p.L133= on NM_031448.6) | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV60364360; called by muse, mutect2, varscan2
- CTC1 | c.258G>T p.S86= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs369789111, COSV100236559; called by muse, mutect2, varscan2
- CUBN | c.9954C>A p.V3318= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100913176; called by muse, mutect2, varscan2
- DNAJA2 | c.531G>T p.G177= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV57694989; called by muse, mutect2, varscan2
- DSP | c.4269C>A p.L1423= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV101131556, COSV101131577; called by muse, mutect2, varscan2
- ERICH3 | c.4296C>G p.G1432= | Silent (SNP) | VAF 26/193 reads (13%) | catalogued as COSV100445084; called by muse, mutect2, varscan2
- FCRL5 | c.462T>C p.P154= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100709155, COSV100709214; called by muse, mutect2
- FER1L6 | c.5316A>G p.L1772= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101206092; called by muse, mutect2, varscan2
- FLT4 | c.3393C>T p.G1131= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs1181531692, COSV56128283; called by muse, mutect2, varscan2
- FNDC1 | c.3465G>T p.A1155= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99796314; called by muse, mutect2
- GRIK3 | c.1557G>T p.L519= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV100902203; called by muse, mutect2
- H2AC13 | c.225G>A p.K75= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV100704415; called by muse, varscan2
- HCK | c.894G>A p.S298= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs771503854, COSV99394347; called by muse, mutect2, varscan2
- HDAC4 | c.1272G>T p.P424= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100613943; called by muse, mutect2, varscan2
- HOXD12 | c.111C>A p.A37= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV66832829; called by muse, mutect2
- IGSF11 | c.1278G>T p.R426= (on ENST00000393775 / NM_001015887.3; = p.R425= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV61173257; called by muse, mutect2, varscan2
- KCNA4 | c.1194C>A p.L398= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100069143; called by muse, mutect2, varscan2
- KCNJ16 | c.54A>G p.P18= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1415967390, COSV99388535; called by muse, mutect2, varscan2
- KIF14 | c.1032C>T p.N344= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs1475317435, COSV100950984; called by muse, mutect2
- MAP3K15 | c.1017T>A p.R339= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100135270; called by muse, mutect2, varscan2
- MYH9 | c.2800C>T p.L934= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs1212381234, COSV99339415; called by muse, mutect2, varscan2
- MYO16 | c.1317G>A p.L439= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99194255; called by muse, mutect2, varscan2
- NLGN2 | c.1278G>A p.V426= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV100081172; called by muse, mutect2, varscan2
- NRCAM | c.2694C>T p.H898= (on ENST00000379028 / NM_001371124.1; = p.H882= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100695144; called by mutect2, varscan2
- OBSL1 | c.2199G>T p.R733= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99217203; called by muse, mutect2, varscan2
- OR11L1 | c.483G>A p.L161= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs1307762716, COSV100869459; called by muse, mutect2, varscan2
- OR2T2 | c.825G>T p.V275= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV100737749; called by muse, varscan2
- OR4A15 | c.777C>A p.P259= | Silent (SNP) | VAF 26/249 reads (10%) | catalogued as COSV59037779; called by muse, mutect2, varscan2
- OR5AN1 | c.636C>T p.A212= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100004413; called by muse, mutect2
- PCDHB2 | c.1812G>T p.L604= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99165944; called by muse, mutect2, varscan2
- PCDHGA2 | c.1911G>A p.A637= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs763228700, COSV99535842; called by muse, mutect2, varscan2
- PCLO | c.1806A>G p.P602= | Silent (SNP) | VAF 55/258 reads (21%) | catalogued as COSV100435153; called by muse, varscan2
- PHF20L1 | c.63A>T p.A21= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV99621682; called by muse, mutect2, varscan2
- PIK3CG | c.2637C>A p.I879= | Silent (SNP) | VAF 48/267 reads (18%) | catalogued as COSV100782621, COSV100783038; called by muse, mutect2, varscan2
- PLPPR1 | c.216G>T p.V72= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100883424; called by muse, mutect2, varscan2
- PRPF6 | c.2499C>T p.A833= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV99412469; called by muse, mutect2, varscan2
- PUS7 | c.1902C>T p.Y634= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as rs747201055, COSV100708601; called by muse, mutect2
- RASSF2 | c.201C>A p.R67= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV101040863; called by muse, varscan2
- RC3H1 | c.3027A>T p.P1009= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV99281612; called by muse, mutect2, varscan2
- RNF213 | c.13326G>A p.T4442= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs762731239; called by muse, mutect2
- RUSC1 | c.885T>C p.I295= | Silent (SNP) | VAF 24/138 reads (17%) | catalogued as COSV99430113; called by muse, mutect2, varscan2
- SALL3 | c.666C>T p.L222= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs746486499, COSV101610031; called by muse, mutect2, varscan2
- SCN3A | c.5613A>T p.R1871= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV51805085, COSV99327761; called by muse, mutect2, varscan2
- SIGLEC12 | c.1158C>A p.G386= (on ENST00000291707 / NM_053003.4; = p.G268= on NM_033329.2) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99389493; called by muse, mutect2, varscan2
- SMOX | c.1470C>T p.S490= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as rs757237978, COSV53869745; called by muse, mutect2, varscan2
- SMTN | c.213G>T p.R71= | Silent (SNP) | VAF 17/213 reads (8%) | catalogued as COSV100294747; called by muse, mutect2
- SNRNP200 | c.5833C>T p.L1945= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as rs778299650, COSV99720490; called by muse, mutect2, varscan2
- SRC | c.564C>T p.C188= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV62439576; called by muse, mutect2, varscan2
- SUGP2 | c.411A>G p.K137= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100432158; called by muse, mutect2, varscan2
- SUMO4 | c.258G>A p.V86= | Silent (SNP) | VAF 20/147 reads (14%) | catalogued as rs1206992487, COSV99645001; called by muse, mutect2, varscan2
- SUPT5H | c.3132C>T p.I1044= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100068012; called by muse, mutect2, varscan2
- TBC1D8 | c.3060C>G p.V1020= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99961548; called by muse, mutect2, varscan2
- TMEM87B | c.822C>T p.S274= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV51715596, COSV99314521; called by muse, mutect2, varscan2
- TRAV26-1 | c.117T>C p.C39= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- TRIM50 | c.120G>C p.L40= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99334202; called by muse, mutect2, varscan2
- TRPA1 | c.1827T>A p.L609= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100084785; called by muse, mutect2, varscan2
- TRRAP | c.3477G>A p.G1159= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as COSV62850202, COSV62854399; called by muse, mutect2, varscan2
- TSPO | c.509G>A p.*170= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99333636; called by muse, mutect2, varscan2
- WDR64 | c.1146C>A p.V382= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100843925, COSV63794001, COSV63800526; called by muse, mutect2, varscan2
- ZC3H3 | c.1170C>T p.S390= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as rs756603863, COSV99368287; called by muse, mutect2, varscan2
- ZEB2 | c.2907A>C p.A969= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as CD072534, COSV100356528; called by muse, mutect2, varscan2
- ZFYVE16 | c.1467C>A p.V489= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100566573; called by muse, mutect2, varscan2
- ZNF407 | c.2256C>T p.H752= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99996304; called by muse, mutect2, varscan2
- ZYG11B | c.1299C>T p.C433= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs879172459, COSV99597675; called by muse, mutect2
- DCHS2 | n.7120C>T | RNA (SNP) | VAF 12/63 reads (19%) | catalogued as COSV61770211; called by muse, mutect2, varscan2
- KHK | c.210-208A>C | Intron (SNP) | VAF 16/95 reads (17%) | catalogued as rs774508030; called by muse, mutect2, varscan2
- MIR145 | n.49G>C | RNA (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- MIR498 | n.4C>A | RNA (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- MORF4 | n.921G>A | RNA (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- MYB | c.1203+986A>T | Intron (SNP) | VAF 22/165 reads (13%) | catalogued as COSV100215040; called by muse, mutect2, varscan2
- PLAGL2 | c.-2C>T | 5'UTR (SNP) | VAF 26/70 reads (37%) | catalogued as COSV55790431; called by muse, mutect2, varscan2
- RHOT1 | c.1739+2897A>G | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100447453; called by muse, mutect2, varscan2
- SERPINA13P | n.691C>T | RNA (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- ZWINT | c.*62C>A | 3'UTR (SNP) | VAF 19/106 reads (18%) | catalogued as COSV100571542; called by muse, mutect2, varscan2
